Somatic mutation profile of tumor specimen TCGA-EA-A5ZE-01A (aliquot TCGA-EA-A5ZE-01A-11D-A28B-09) from TCGA case TCGA-EA-A5ZE, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 54.4 years (19,868 days).
Specimen TCGA-EA-A5ZE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13d20f69-e394-45e1-befc-bacdb02dc952.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A5ZE-10A (Blood Derived Normal), aliquot TCGA-EA-A5ZE-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64beefdb-ce5b-4dd3-b22c-dccd62f97580

The open-access MAF lists 60 somatic variants for this specimen: 38 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 20, Frame Shift Ins 3, In Frame Del 1, Frame Shift Del 1, 5'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs587778847, CD034936, CM030504, COSV57307935, COSV57323260; ClinVar: pathogenic; called by muse, varscan2
- ADGRG4 | c.1130C>G p.S377C | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV99055314; called by muse, mutect2
- BOC | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769031341; called by muse, varscan2
- CALU | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as rs751087084; called by muse, mutect2, varscan2
- DLGAP3 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1340940463, COSV52393413; called by muse, mutect2, varscan2
- EMILIN2 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54424069; called by muse, mutect2, varscan2
- FBN2 | c.2362C>T p.R788C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs746122770, COSV52497615; called by muse, mutect2, varscan2
- GDF6 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1199035850, COSV54622527; called by muse, mutect2, varscan2
- H3C11 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV100137683, COSV58899983; called by muse, mutect2, varscan2
- IGSF10 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); catalogued as rs372971163; called by muse, mutect2, varscan2
- KIF1A | c.3982C>T p.R1328C (on ENST00000320389 / NM_001379639.1; = p.R1320C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1444137658, COSV100239976; called by muse, mutect2, varscan2
- KRTAP27-1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs927078704, COSV67001134; called by muse, mutect2, varscan2
- LIFR | c.3273dup p.Q1092Sfs*20 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | catalogued as rs1165606146; called by mutect2, pindel, varscan2
- MUC4 | c.15316C>T p.R5106W (on ENST00000463781 / NM_018406.7; = p.R870W on NM_004532.6) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1338980774, COSV100203573; called by muse, mutect2, varscan2
- NDN | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1217310499, COSV59358436; called by muse, mutect2, varscan2
- PRSS55 | c.756dup p.P253Afs*10 | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | catalogued as rs751829343; called by mutect2, pindel, varscan2
- RNF125 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0.134); catalogued as rs201216500; called by muse, mutect2, varscan2
- SSTR5 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs747219171; called by muse, mutect2, varscan2
- SVIL | c.2104A>G p.R702G (on ENST00000355867 / NM_021738.3; = p.R308G on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63444738; called by muse, mutect2, varscan2
- TMCO5A | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1348893959; called by muse, mutect2, varscan2
- CNTN1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- COL20A1 | c.1858A>T p.T620S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CYGB | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- FBXO40 | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXD4L3 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by mutect2, varscan2
- FOXQ1 | c.363del p.Y122Tfs*19 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- HSD11B2 | c.346T>G p.L116V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- MED28 | chr4:17614629 del TGGATCTCTCTTGCGCCATTCCAAACA | Missense Mutation (DEL) | VAF 20/34 reads (59%) | called by mutect2, pindel, varscan2
- OGFRL1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PMP2 | c.242C>G p.T81S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNF115 | c.301_309del p.R101_N103del | In Frame Del (DEL) | VAF 32/102 reads (31%) | called by mutect2, pindel, varscan2
- SCRN1 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SMG7 | c.2669dup p.D891Rfs*24 | Frame Shift Ins (INS) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- STXBP5 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2
- TDRD6 | c.4225G>A p.A1409T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- TET1 | c.1979A>G p.D660G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS50 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- VPS52 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ACTA2 | c.1065G>A p.Q355= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV99826974; called by muse, mutect2, varscan2
- ANKRD30A | c.1638G>A p.L546= (on ENST00000611781; = p.L490= on NM_052997.2) | Silent (SNP) | VAF 32/110 reads (29%) | called by muse, mutect2, varscan2
- APC | c.6864G>A p.Q2288= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- ASPM | c.3663G>A p.R1221= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as CD033166; called by muse, mutect2, varscan2
- BRAT1 | c.1434C>G p.L478= | Silent (SNP) | VAF 22/99 reads (22%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.2859T>C p.V953= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs1196073227, COSV99353416; called by muse, mutect2, varscan2
- FAM160A2 | c.1293C>T p.H431= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs368609593; called by muse, mutect2, varscan2
- GJA1 | c.450G>T p.G150= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV99247433; called by muse, mutect2, varscan2
- GOLM1 | c.138C>T p.I46= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs781078106, COSV99974212; called by muse, mutect2, varscan2
- GPX6 | c.432A>G p.K144= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV100724780; called by muse, mutect2, varscan2
- GRIN2A | c.2058T>C p.P686= | Silent (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- HDAC2 | c.624C>T p.G208= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- HTT | c.5347C>T p.L1783= | Silent (SNP) | VAF 46/71 reads (65%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.1293G>T p.L431= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- IRX6 | c.1320G>A p.P440= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs750264638; called by muse, mutect2, varscan2
- KCNK9 | c.660C>T p.Y220= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs111826894, COSV57280572; ClinVar: likely benign; called by muse, mutect2, varscan2
- LDHC | c.540C>T p.V180= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs1404743287, COSV99772377; called by muse, mutect2, varscan2
- MKRN3 | c.456G>A p.P152= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs536725835, COSV100091899; called by muse, mutect2, varscan2
- RB1 | c.1608C>T p.I536= | Silent (SNP) | VAF 18/26 reads (69%) | called by muse, mutect2, varscan2
- SCN2A | c.906G>A p.G302= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99331104; called by muse, mutect2, varscan2
- CCDC28A | c.-66G>A | 5'UTR (SNP) | VAF 57/173 reads (33%) | called by muse, mutect2, varscan2
- UAP1L1 | c.495-113C>T | Intron (SNP) | VAF 13/58 reads (22%) | called by mutect2, varscan2
